Gene-level copy-number profile of tumor specimen HTMCP-02-03-01004-01A from CGCI case HTMCP-02-03-01004, project CGCI-HTMCP-LC (HIV+ Tumor Molecular Characterization Project - Lung Cancer). Sex at birth: male; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.9 years (21,863 days).
Specimen HTMCP-02-03-01004-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 03fa0000-466e-4f91-bbef-7ed0220e9856.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-02-03-01004-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,730 have no estimate.
https://portal.gdc.cancer.gov/files/41799c13-5db6-4175-8205-2b6c54dc5fd6

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 563; copy number 1: 43; copy number 2: 554; copy number 3: 11,684; copy number 4: 15,409; copy number 5: 16,723; copy number 6: 6,917; copy number 7: 3,289; copy number 8: 1,219; copy number 9: 424; copy number 10: 68; copy number 11: 202; copy number 12: 723; copy number 13: 239; copy number 14: 405; copy number 16: 18; copy number 17: 199; copy number 22: 28; copy number 23: 67; copy number 24: 13; copy number 25: 11; copy number 27: 11; copy number 28: 5; copy number 33: 9; copy number 35: 52; copy number 39: 15; copy number 61: 3.

Homozygous deletions (total copy number 0; autosomes only): 51 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:7,295,014–7,542,450, 17 genes: FAM90A20P, FAM66B, DEFB109B, USP17L1, USP17L4, AC130360.1, ZNF705G, DEFB108C, DEFB4B, HSPD1P3, DEFB103B, SPAG11B, DEFB104B, DEFB106B, DEFB105B, DEFB107B, PRR23D1.
- chr8:12,356,136–12,388,296, 4 genes: ZNF705CP, FAM66A, AC087203.1, AC087203.2.
- chr9:39,983,793–40,106,611, 1 gene (within-gene range 0–4): AL772307.1.
- chr9:40,105,822–40,122,540, 2 genes: AL773545.3, CDRT15P14.
- chr9:40,755,407–40,767,875, 2 genes (within-gene range 0–3): AL353626.3, RNU6-156P.
- chr9:60,914,407–60,964,196, 5 genes: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr14:18,692,032–18,712,643, 4 genes: RPL22P20, CR383656.4, CR383656.2, NF1P10.
- chr15:21,990,074–22,126,434, 9 genes (within-gene range 0–2): AC134980.1, OR11H3P, AC134980.2, OR11K1P, OR4Q1P, OR4H6P, OR4M2, OR4N4, OR4N3P.
- chr21:9,068,361–9,129,752, 3 genes: TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 2,000 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:257,864–522,928, 10 genes, copy number 12 (within-gene range 6–12): AP006222.1, AP006222.2, RPL23AP24, AL732372.1, AL732372.2, WBP1LP7, OR4F29, CICP7, AL732372.3, U6.
- chr6:32,517,353–32,530,287, 1 gene, copy number 11: HLA-DRB5.
- chr7:37,032–975,549, 24 genes, copy number 14: AC215522.1, AC093627.1, AC093627.6, AC093627.5, AC093627.4, AC093627.7, AC093627.2, AC093627.3, FAM20C, AC145676.1, FOXL3, AC226118.1, AC147651.1, PDGFA, HRAT92, PRKAR1B, PRKAR1B-AS2, PRKAR1B-AS1, DNAAF5, SUN1, GET4, AC073957.3, ADAP1, COX19.
- chr7:26,551,686–35,038,271, 178 genes, copy number 11–13 (broad region; genes not listed).
- chr8:7,592,006–7,601,267, 2 genes, copy number 13: OR7E157P, AC134684.1.
- chr8:59,455,885–70,078,032, 155 genes, copy number 11–12 (broad region; genes not listed).
- chr8:72,357,728–73,370,601, 23 genes, copy number 12: RNA5SP271, AC124293.1, AC011131.1, KCNB2, HAUS1P3, AC013562.2, AC013562.1, AC090735.1, AC022893.2, TERF1, RNU6-285P, AC022893.3, AC022893.1, SBSPON, AC100823.1, AC100823.2, C8orf89, PRXL2AP2, RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2.
- chr8:78,805,293–145,066,685, 1,025 genes, copy number 11–23 (within-gene range 8–23) (broad region; genes not listed).
- chr9:43,109,866–60,547,154, 3 genes, copy number 12: FP325317.1, FP325317.2, BX088702.1.
- chr9:134,641,803–138,253,217, 171 genes, copy number 11–13 (broad region; genes not listed).
- chr12:18,424,663–20,136,163, 24 genes, copy number 22: AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, LINC02468.
- chr12:21,264,600–23,251,499, 36 genes, copy number 24–61: SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1.
- chr12:54,276,631–54,345,083, 1 gene, copy number 28 (within-gene range 4–28): AC078778.1.
- chr12:54,301,202–54,351,846, 4 genes, copy number 28: COPZ1, RNU6-950P, MIR148B, RN7SL744P.
- chr12:56,116,590–56,512,703, 36 genes, copy number 11–39: RPL41, ESYT1, ZC3H10, AC034102.7, AC034102.6, AC034102.5, MYL6B, MYL6, SMARCC2, AC073896.4, RNF41, NABP2, SLC39A5, ANKRD52, COQ10A, AC073896.5, CS, AC073896.1, AC073896.2, AC073896.3, CNPY2, PAN2, IL23A, STAT2, RNU7-40P, APOF, APONP, AC025574.1, AC024884.2, AC024884.1, TIMELESS, MIP, AC097104.1, SPRYD4, GLS2, HSPD1P4.
- chr12:57,216,794–57,896,846, 52 genes, copy number 35: NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3.
- chr12:71,938,845–72,728,844, 7 genes, copy number 11: TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2, AC133480.1.
- chr19:27,638,483–30,038,181, 57 genes, copy number 12–22: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1, AC005307.1, AC005394.2, AC005381.1, AC005394.1, AC005616.1, AC079466.2, AC079466.1, AC005524.1, MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1.
- chr19:33,067,175–36,777,078, 191 genes, copy number 12–25 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 43. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
